Somatic mutation profile of tumor specimen TCGA-94-A4VJ-01A (aliquot TCGA-94-A4VJ-01A-11D-A257-08) from TCGA case TCGA-94-A4VJ, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 71.2 years (25,991 days).
Specimen TCGA-94-A4VJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 925d113f-2231-478a-8b56-fb9b1ba0658f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-94-A4VJ-10A (Blood Derived Normal), aliquot TCGA-94-A4VJ-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2aaef353-09a5-4fd0-b75b-6155056c3342

The open-access MAF lists 437 somatic variants for this specimen: 334 protein-altering or splice-affecting, 93 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 292, Silent 93, Nonsense Mutation 24, Splice Site 6, Frame Shift Del 6, Intron 5, RNA 5, Splice Region 4, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRNG | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777219451, CM062518, COSV99286158; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.5737C>G p.L1913V | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.803); catalogued as COSV101330190; called by muse, mutect2, varscan2
- ABCB4 | c.1985T>G p.L662R | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99711350; called by muse, mutect2
- ACTN2 | c.139T>A p.W47R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63976948; called by muse, mutect2, varscan2
- ACTN2 | c.2012T>C p.L671P | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100857050; called by muse, mutect2, varscan2
- ADCY10 | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100897104; called by muse, mutect2, varscan2
- ADGRG2 | c.2996G>T p.R999L (on ENST00000379869 / NM_001079858.3; = p.R996L on NM_005756.4) | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.825); catalogued as rs766102915, COSV100492724; called by muse, mutect2, varscan2
- ADGRV1 | c.6221T>A p.V2074D | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101316557; called by muse, mutect2, varscan2
- AF196969.1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.914); catalogued as COSV99339439; called by muse, mutect2, varscan2
- AIRE | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99381448; called by muse, mutect2, varscan2
- AKT2 | c.1236C>G p.I412M | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.2); catalogued as COSV100251857; called by muse, mutect2
- ALS2 | c.536A>T p.Q179L | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99970095; called by muse, mutect2, varscan2
- AMDHD2 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99566170; called by muse, mutect2
- AMPH | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100341767; called by muse, mutect2, varscan2
- AMY2B | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.42); catalogued as COSV100796508, COSV63716747; called by muse, mutect2, varscan2
- ANKRD11 | c.1081G>T p.V361L | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as COSV56371786, COSV99968638; called by muse, mutect2, varscan2
- AP3B2 | c.3124G>T p.G1042W (on ENST00000261722; = p.G1036W on NM_004644.5) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55610185; called by muse, mutect2, varscan2
- ARHGAP5 | c.2554A>G p.I852V | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as rs762982624, COSV100565717; called by muse, mutect2, varscan2
- ASCL1 | c.372C>A p.N124K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99902170; called by muse, mutect2, varscan2
- ASH1L | c.6530A>T p.E2177V (on ENST00000368346 / NM_001366177.2; = p.E2172V on NM_018489.3) | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100853609; called by muse, mutect2, varscan2
- ATCAY | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 10/75 reads (13%) | catalogued as COSV100009048; called by muse, mutect2, varscan2
- ATG9B | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 113/208 reads (54%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV100939938; called by muse, mutect2, varscan2
- ATL1 | c.655T>G p.W219G | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100613327; called by muse, mutect2, varscan2
- ATL1 | c.656G>T p.W219L | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100613328; called by muse, mutect2, varscan2
- ATXN1 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as rs761508472, COSV99787917; called by muse, mutect2, varscan2
- BMP3 | c.271C>A p.L91M | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV99262062; called by muse, mutect2, varscan2
- BRCA1 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as COSV58795275; called by muse, mutect2, varscan2
- BRD8 | c.703G>T p.E235* (on ENST00000254900 / NM_139199.2; = p.E308* on NM_006696.4) | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | catalogued as COSV99137695; called by muse, mutect2, varscan2
- BTBD6 | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100527804; called by muse, mutect2, varscan2
- BTG4 | c.489C>A p.S163R | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV100604623; called by muse, mutect2, varscan2
- C3 | c.2996G>T p.R999L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV55578014, COSV99837288; called by muse, mutect2, varscan2
- C7orf50 | c.327G>T p.W109C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100657726; called by muse, mutect2, varscan2
- CACNA1F | c.2803T>C p.F935L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100545412; called by muse, mutect2, varscan2
- CACNA1H | c.6770G>A p.R2257Q | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.074); catalogued as rs775972605, COSV52354851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG5 | c.431C>A p.S144Y | Missense Mutation (SNP) | VAF 61/103 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV50055021, COSV99400840; called by muse, mutect2, varscan2
- CAPN13 | c.298G>T p.G100* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV99699889, COSV99701133; called by muse, mutect2, varscan2
- CARMIL2 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs1233433802, COSV100576322; called by muse, mutect2
- CCDC102B | c.1524G>T p.R508S | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs1232958262, COSV100104976; called by muse, mutect2, varscan2
- CCN3 | c.312G>T p.A104= | Splice Region (SNP) | VAF 35/112 reads (31%) | catalogued as COSV52383129, COSV99423387; called by muse, mutect2, varscan2
- CCNF | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99564198; called by muse, mutect2, varscan2
- CCR8 | c.737C>A p.A246E | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100413203; called by muse, mutect2, varscan2
- CDC73 | c.1513C>T p.H505Y | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as rs1558326147, COSV100814012; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH8 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760266740, COSV100180188, COSV100184277; called by muse, mutect2, varscan2
- CENPE | c.5992G>C p.E1998Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.59); catalogued as COSV99479235; called by muse, mutect2, varscan2
- CEP68 | c.2070G>C p.E690D | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99561298; called by muse, mutect2, varscan2
- CEP72 | c.773G>T p.S258I | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV53792776; called by muse, mutect2, varscan2
- CHFR | c.180C>A p.H60Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99905758; called by muse, mutect2, varscan2
- CHGB | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.138); catalogued as COSV100973109; called by muse, mutect2, varscan2
- CLIP1 | c.4316G>T p.*1439Lext*1 (on ENST00000620786 / NM_001247997.1; = p.*1428Lext*1 on NM_002956.2) | Nonstop Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as COSV100212430; called by muse, mutect2, varscan2
- CMKLR1 | c.267C>A p.N89K (on ENST00000312143 / NM_001142344.2; = p.N87K on NM_004072.3) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100379629; called by muse, mutect2, varscan2
- CNTN5 | c.779A>T p.Q260L | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99681559; called by muse, mutect2
- CNTNAP5 | c.1151C>A p.P384H | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV101443078, COSV70483254; called by muse, mutect2, varscan2
- COL10A1 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as rs372281591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL11A1 | c.4810G>T p.A1604S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100618098; called by muse, mutect2, varscan2
- COL11A1 | c.1189C>A p.P397T | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100618010, COSV62179153, COSV62185194; called by muse, mutect2, varscan2
- COL12A1 | c.238T>G p.L80V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100486586; called by muse, mutect2, varscan2
- COL20A1 | c.2177G>T p.R726L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV58914150, COSV58923877; called by muse, mutect2, varscan2
- COL4A3 | c.1601C>G p.P534R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.499); catalogued as COSV101170544, COSV67421317; called by muse, mutect2, varscan2
- COLGALT1 | c.1208G>T p.R403L | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99394766, COSV99395301; called by muse, mutect2, varscan2
- COQ9 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99346015; called by muse, mutect2
- CORIN | c.111G>C p.K37N | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99904511; called by muse, mutect2, varscan2
- CORO1B | c.107G>A p.W36* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as COSV100396786; called by muse, mutect2, varscan2
- CPNE8 | c.748A>T p.T250S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as COSV100505162, COSV104403188; called by muse, mutect2, varscan2
- CSMD1 | c.1349T>C p.V450A (on ENST00000520002; = p.V449A on NM_033225.6) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as COSV101225588; called by muse, mutect2
- CSNK1D | c.1113G>T p.M371I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.013); catalogued as COSV99484780; called by muse, mutect2, varscan2
- CUX2 | c.989C>A p.A330E | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV99920865; called by muse, mutect2, varscan2
- DAB2IP | c.768G>T p.W256C (on ENST00000408936; = p.W228C on NM_032552.3) | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52260873; called by muse, mutect2, varscan2
- DCT | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100986308, COSV100986313; called by muse, mutect2, varscan2
- DDX18 | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV54307349; called by muse, mutect2, varscan2
- DHRSX | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV100586093; called by muse, mutect2, varscan2
- DHX8 | c.1841G>A p.G614E | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374703434; called by muse, mutect2, varscan2
- DIAPH3 | c.1955T>G p.L652* (on ENST00000400324 / NM_001042517.2; = p.L389* on NM_030932.3) | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99934543, COSV99934655; called by muse, mutect2, varscan2
- DICER1 | c.4276A>T p.S1426C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV100602576; called by muse, mutect2, varscan2
- DIO1 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV99301173; called by muse, mutect2, varscan2
- DMD | c.10870A>G p.S3624G | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV100629456; called by muse, mutect2, varscan2
- DMD | c.5783C>A p.A1928E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.925); catalogued as COSV63794384; called by muse, mutect2, varscan2
- DMD | c.2950G>T p.A984S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as COSV100821523, COSV100822953; called by muse, mutect2
- DMXL1 | c.463A>T p.N155Y | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV100225034; called by muse, mutect2, varscan2
- DNAH3 | c.1563G>T p.K521N | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99770759; called by muse, mutect2, varscan2
- DUSP1 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV99496062; called by muse, mutect2, varscan2
- EBF3 | c.822G>T p.W274C (on ENST00000355311 / NM_001375392.1; = p.W265C on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62478329; called by muse, mutect2, varscan2
- EGFLAM | c.601A>G p.M201V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as rs781435086, COSV100473631; called by muse, mutect2, varscan2
- EIF2D | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs782532326, COSV55113967, COSV99663085; called by muse, mutect2, varscan2
- ELP4 | c.1040G>T p.G347V (on ENST00000350638; = p.G346V on NM_019040.5) | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs984654481, COSV100635905, COSV63352191; called by muse, mutect2, varscan2
- EMILIN1 | c.1831G>A p.G611S | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.341); catalogued as rs761704114, COSV53157429, COSV99566569; called by muse, mutect2, varscan2
- ENOX1 | c.1732C>G p.L578V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99817286; called by muse, mutect2, varscan2
- EPB41L3 | c.736G>T p.G246W | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100550356; called by muse, mutect2, varscan2
- EPHA6 | c.479A>G p.H160R | Missense Mutation (SNP) | VAF 97/232 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.547); catalogued as rs1040503797, COSV101065716; called by muse, mutect2, varscan2
- EPHB4 | c.2392A>G p.T798A | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100639671; called by muse, mutect2, varscan2
- EPS15L1 | c.899A>C p.K300T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99933744; called by muse, mutect2, varscan2
- ERBB4 | c.3847G>T p.E1283* | Nonsense Mutation (SNP) | VAF 32/82 reads (39%) | catalogued as COSV100728029, COSV61513416, COSV61521979; called by muse, mutect2, varscan2
- ERBB4 | c.828G>T p.E276D | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.975); catalogued as COSV53572268; called by muse, mutect2, varscan2
- ERV3-1 | c.357A>T p.L119F | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99276136; called by muse, mutect2
- ESRRG | c.1324G>T p.G442C | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753936; called by muse, mutect2, varscan2
- F5 | c.4868A>G p.Y1623C | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100889258; called by muse, mutect2, varscan2
- FAM193A | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100219607; called by muse, mutect2
- FANCB | c.532A>C p.N178H | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100146704; called by muse, mutect2, varscan2
- FAP | c.152C>G p.T51R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.378); catalogued as COSV99502566; called by muse, mutect2, varscan2
- FAT1 | c.3805G>T p.E1269* | Nonsense Mutation (SNP) | VAF 116/230 reads (50%) | catalogued as COSV101499658; called by muse, mutect2, varscan2
- FAT4 | c.6280G>T p.G2094* | Nonsense Mutation (SNP) | VAF 115/282 reads (41%) | catalogued as COSV100630291; called by muse, mutect2, varscan2
- FFAR1 | c.450G>C p.W150C | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV99323791; called by muse, mutect2, varscan2
- FKBP15 | c.3479G>T p.R1160L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); catalogued as COSV99439864; called by muse, mutect2, varscan2
- FLNA | c.7807G>A p.E2603K (on ENST00000369850 / NM_001110556.2; = p.E2595K on NM_001456.3) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100774781, COSV100775287; called by muse, mutect2
- FNDC4 | c.658G>T p.G220W | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV99254074; called by muse, mutect2, varscan2
- FOXD4L5 | c.838G>T p.G280W | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs781582393, COSV101073104, COSV66241318; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1562C>G p.P521R | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100438146; called by muse, mutect2, varscan2
- FRAS1 | c.9860G>A p.G3287E | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1325859575, COSV53640938; called by muse, mutect2, varscan2
- FSTL5 | c.2230T>C p.F744L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1489373059, COSV100061545; called by muse, mutect2, varscan2
- FTHL17 | c.160C>A p.R54S | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.215); catalogued as COSV100784419, COSV63267934; called by muse, mutect2, varscan2
- FTSJ3 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 80/250 reads (32%) | catalogued as COSV100037463; called by muse, mutect2, varscan2
- FYTTD1 | c.451A>T p.R151W | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99611992; called by muse, mutect2, varscan2
- GAB3 | c.706C>A p.H236N | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100850707; called by muse, mutect2, varscan2
- GABRG2 | c.373C>A p.R125S | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62715377, COSV62715450; called by muse, mutect2, varscan2
- GATA1 | c.335C>A p.T112N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1193519227, COSV100936874; called by muse, mutect2, varscan2
- GPC5 | c.1280G>C p.S427T | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100996173; called by muse, mutect2, varscan2
- GRPEL2 | c.659A>G p.E220G | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as COSV100249852; called by muse, mutect2, varscan2
- GTDC1 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV99601961; called by muse, mutect2, varscan2
- GTPBP6 | c.754T>C p.S252P | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as COSV100397851; called by muse, mutect2, varscan2
- HCN2 | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); catalogued as COSV52114818, COSV99242331; called by muse, mutect2, varscan2
- HECW2 | c.3310G>C p.D1104H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV99649139; called by muse, mutect2, varscan2
- HERC4 | c.2101G>A p.V701M (on ENST00000395198 / NM_022079.3; = p.V693M on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.243); catalogued as COSV99517529; called by muse, mutect2, varscan2
- HIP1 | c.1391A>T p.N464I | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV100418189, COSV61183792; called by muse, mutect2, varscan2
- HLX | c.814T>C p.Y272H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as COSV100854637; called by muse, varscan2
- HNRNPDL | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); catalogued as COSV99787230; called by muse, mutect2, varscan2
- HSPB9 | c.434C>G p.P145R | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV99863428, COSV99863715, COSV99863719; called by muse, mutect2, varscan2
- HTR1B | c.551C>A p.P184H | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV64051900; called by muse, mutect2, varscan2
- IFT140 | c.3906A>C p.K1302N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794524; called by muse, mutect2, varscan2
- IGKV1-12 | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs1558637469; called by muse, mutect2, varscan2
- IGLC3 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 26/92 reads (28%) | PolyPhen benign (0.17); catalogued as rs758947730; called by muse, mutect2, varscan2
- IGSF11 | c.177G>T p.W59C (on ENST00000393775 / NM_001015887.3; = p.W58C on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61178580; called by muse, mutect2, varscan2
- IKBIP | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.525); catalogued as COSV100689897; called by muse, varscan2
- IL17RD | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99578194; called by muse, mutect2, varscan2
- ITPR2 | c.1039G>C p.G347R | Missense Mutation (SNP) | VAF 142/261 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as rs1054169785, COSV101190185; called by muse, mutect2, varscan2
- IZUMO1R | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100126936; called by muse, mutect2, varscan2
- KALRN | c.1004A>C p.Q335P | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.987); catalogued as COSV53771845, COSV99567452; called by muse, mutect2, varscan2
- KAT8 | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99571822; called by muse, mutect2, varscan2
- KCNA3 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871314; called by muse, mutect2, varscan2
- KCNA4 | c.1150T>A p.F384I | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.161); catalogued as COSV100069292; called by muse, mutect2, varscan2
- KCNK10 | c.1469C>A p.T490K | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV100069359; called by muse, mutect2, varscan2
- KDM5B | c.292C>G p.R98G | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52514921, COSV99351442; called by muse, mutect2, varscan2
- KDR | c.2608T>A p.L870M | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99818764; called by muse, mutect2, varscan2
- KIFAP3 | c.1090A>T p.T364S | Missense Mutation (SNP) | VAF 64/115 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV100810962; called by muse, mutect2, varscan2
- KLHL1 | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.315); catalogued as COSV100918186, COSV64786221; called by muse, mutect2, varscan2
- KMT2D | c.5698G>T p.G1900C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99985978; called by muse, mutect2, varscan2
- KNDC1 | c.1396T>C p.C466R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100466299; called by muse, mutect2, varscan2
- KNL1 | c.6842C>T p.T2281I (on ENST00000346991 / NM_170589.5; = p.T2255I on NM_144508.5) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.698); catalogued as rs1439091838, COSV100707086; called by muse, mutect2, varscan2
- KRT36 | c.157A>T p.R53W | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.629); catalogued as COSV100057754; called by muse, mutect2, varscan2
- LAMA1 | c.1547C>G p.S516C | Missense Mutation (SNP) | VAF 103/333 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.438); catalogued as COSV101057826, COSV67532597; called by muse, mutect2, varscan2
- LAMA2 | c.6179A>T p.Q2060L | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV101370863; called by muse, mutect2, varscan2
- LAX1 | c.793T>C p.S265P | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1466882162, COSV100920099; called by muse, mutect2, varscan2
- LHFPL3 | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.457); catalogued as COSV101308967, COSV67820548; called by muse, mutect2, varscan2
- LHX8 | c.861T>A p.N287K | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV99634458; called by muse, mutect2, varscan2
- LMTK2 | c.4364C>G p.A1455G | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99807833; called by muse, mutect2, varscan2
- LRP1B | c.4580C>A p.A1527D | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101261429; called by muse, mutect2, varscan2
- LRP2 | c.13236G>T p.M4412I | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99790355; called by muse, mutect2, varscan2
- LRP2 | c.10718A>G p.N3573S | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); catalogued as rs1558996039, COSV55555679, COSV99790357; called by muse, varscan2
- LRRCC1 | c.2767G>C p.E923Q | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.014); catalogued as COSV100835505; called by muse, mutect2, varscan2
- LRRK2 | c.20A>C p.Q7P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100111189; called by muse, mutect2, varscan2
- MAGEA12 | c.197A>T p.Q66L | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100757084; called by muse, mutect2, varscan2
- MAGEB10 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV63310963, COSV63312330; called by muse, mutect2, varscan2
- MAGEB4 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs1356862736, COSV100854641, COSV100854822; called by muse, mutect2, varscan2
- MAST4 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.243); catalogued as COSV68238570; called by muse, mutect2, varscan2
- MC5R | c.272G>T p.W91L | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.893); catalogued as COSV100229176; called by muse, mutect2, varscan2
- MDGA2 | c.2002A>T p.K668* (on ENST00000399232 / NM_001113498.2; = p.K370* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 13/87 reads (15%) | catalogued as COSV100638557; called by muse, mutect2, varscan2
- MED12 | c.3974G>T p.C1325F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV100380081; called by muse, mutect2, varscan2
- MED13L | c.6049G>T p.G2017W | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99930242; called by muse, mutect2, varscan2
- MFSD9 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99302314; called by muse, mutect2, varscan2
- MGAM | c.5146A>T p.I1716F | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV101527773; called by muse, mutect2, varscan2
- MME | c.439T>C p.S147P | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.19); catalogued as COSV100852553; called by muse, mutect2, varscan2
- MOAP1 | c.426G>T p.W142C | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.54); catalogued as rs1436689865, COSV99365825; called by muse, mutect2, varscan2
- MORC1 | c.593T>A p.L198Q | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99227846; called by muse, mutect2
- MOSPD2 | c.1092G>T p.V364= | Splice Region (SNP) | VAF 41/196 reads (21%) | catalogued as COSV100996940; called by muse, mutect2, varscan2
- MROH7 | c.2520+1G>T p.X840_splice | Splice Site (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100272697, COSV59872019; called by muse, mutect2, varscan2
- MTMR11 | c.391A>C p.I131L (on ENST00000439741 / NM_001145862.2; = p.I59L on NM_181873.3) | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100809320; called by muse, mutect2, varscan2
- MTMR12 | c.1848G>T p.W616C | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99374104; called by muse, mutect2, varscan2
- MUC16 | c.2261C>A p.T754K | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); catalogued as COSV101201812; called by muse, mutect2, varscan2
- MUC17 | c.6544T>A p.S2182T | Missense Mutation (SNP) | VAF 78/745 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100075135; called by muse, mutect2, varscan2
- MYL3 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 43/165 reads (26%) | catalogued as COSV52767929, COSV99439598; called by muse, mutect2, varscan2
- MYOM1 | c.2313C>G p.Y771* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as COSV99868497; called by muse, mutect2, varscan2
- NCR1 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.802); catalogued as COSV99401185; called by muse, mutect2, varscan2
- NDN | c.324C>G p.Y108* | Nonsense Mutation (SNP) | VAF 35/84 reads (42%) | catalogued as COSV100086739, COSV59360029; called by muse, mutect2, varscan2
- NLRP8 | c.3068G>C p.R1023P | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.282); catalogued as COSV52590311, COSV99406013; called by muse, mutect2, varscan2
- NOS2 | c.1249G>T p.E417* | Nonsense Mutation (SNP) | VAF 21/126 reads (17%) | catalogued as COSV100569904; called by muse, mutect2, varscan2
- NOTCH1 | c.3449C>G p.S1150* | Nonsense Mutation (SNP) | VAF 27/58 reads (47%) | catalogued as COSV53036428, COSV99491994; called by muse, mutect2, varscan2
- NR1H2 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as rs542914341, COSV99516554; called by muse, mutect2, varscan2
- NRXN1 | c.3778G>A p.G1260S | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.116); catalogued as COSV100640757; called by muse, mutect2
- NTRK3 | c.2231A>T p.Y744F (on ENST00000360948 / NM_001012338.2; = p.Y730F on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100713979; called by muse, mutect2, varscan2
- OR2A5 | c.458C>G p.S153C | Missense Mutation (SNP) | VAF 81/155 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV101278861; called by muse, mutect2, varscan2
- OR52A1 | c.445A>G p.M149V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs776668078, COSV100200576; called by muse, mutect2, varscan2
- OR52A5 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as rs1301742962, COSV100263360; called by muse, mutect2, varscan2
- OR5B12 | c.503G>C p.R168T | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); catalogued as COSV100222579, COSV56904724; called by muse, mutect2, varscan2
- OR5T3 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100282944; called by muse, mutect2, varscan2
- OR6F1 | c.217T>A p.Y73N | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV100129480; called by muse, mutect2, varscan2
- OR6N2 | c.314A>T p.H105L | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV100210515; called by muse, mutect2, varscan2
- OR6N2 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100210517; called by muse, mutect2, varscan2
- OR8B8 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.925); catalogued as COSV100045284; called by muse, mutect2, varscan2
- P2RY1 | c.460G>T p.V154L | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as COSV100521803; called by muse, mutect2, varscan2
- PAPLN | c.2244T>C p.H748= (on ENST00000554301; = p.H721= on NM_173462.4) | Splice Region (SNP) | VAF 13/38 reads (34%) | catalogued as rs1410950894, COSV99390484; called by muse, mutect2, varscan2
- PBX3 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100655601; called by muse, mutect2, varscan2
- PBX3 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV100655602; called by muse, mutect2, varscan2
- PCDH15 | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV57320758; called by muse, mutect2, varscan2
- PCDHB4 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 96/282 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.232); catalogued as rs1185586111, COSV99522521; called by muse, mutect2, varscan2
- PCDHGA12 | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99342461; called by muse, mutect2, varscan2
- PCLO | c.839G>T p.R280M | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV100438128; called by muse, mutect2
- PCSK6 | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs762741137, COSV100624497; called by muse, mutect2, varscan2
- PDE10A | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 43/67 reads (64%) | catalogued as COSV63103693; called by muse, mutect2, varscan2
- PDE3A | c.1518G>T p.K506N | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs754465163, COSV100762828, COSV100762829; called by muse, mutect2
- PDE6C | c.1094del p.P365Lfs*13 | Frame Shift Del (DEL) | VAF 15/154 reads (10%) | catalogued as COSV65115459; called by mutect2, pindel, varscan2
- PDZD2 | c.3008G>A p.R1003H | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs753028675, COSV56865963, COSV99224254; called by muse, mutect2, varscan2
- PDZD8 | c.976A>C p.T326P | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1402160379, COSV100559656; called by muse, mutect2
- PDZRN4 | c.2869C>T p.R957C (on ENST00000402685 / NM_001164595.2; = p.R699C on NM_013377.4) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1263769082, COSV100115526; called by muse, mutect2, varscan2
- PGAP6 | c.1160G>T p.R387L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99170803; called by muse, mutect2, varscan2
- PHEX | c.1646-1G>T p.X549_splice | Splice Site (SNP) | VAF 24/133 reads (18%) | catalogued as rs1324553227, COSV65077466, COSV65078745; called by muse, mutect2, varscan2
- PIK3C2G | c.3908C>T p.P1303L (on ENST00000676171; = p.P1262L on NM_004570.5) | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99854120; called by muse, mutect2
- PITPNM2 | c.2141G>T p.R714M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV99759677; called by muse, mutect2, varscan2
- PLEC | c.2493G>T p.E831D (on ENST00000322810 / NM_201380.4; = p.E721D on NM_000445.5) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100519261; called by muse, mutect2
- PLEKHA5 | c.1236G>T p.Q412H | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV100164784; called by muse, mutect2, varscan2
- PLPPR4 | c.1250T>C p.L417S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100926946; called by muse, mutect2, varscan2
- PLXDC2 | c.338A>G p.H113R | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101023295; called by muse, mutect2, varscan2
- PLXNA4 | c.2983C>A p.L995I | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV58141049; called by muse, mutect2, varscan2
- POM121L12 | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101374991; called by muse, mutect2, varscan2
- POPDC3 | c.820C>A p.R274S | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99633551; called by muse, mutect2, varscan2
- PRAMEF2 | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 92/455 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV99535738; called by muse, mutect2, varscan2
- PRDM16 | c.1721G>T p.G574V | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as COSV99579059; called by muse, mutect2, varscan2
- PRKG1 | c.486G>C p.K162N | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as COSV100909771, COSV100910028; called by muse, mutect2, varscan2
- PRSS36 | c.80G>T p.S27I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV99191341; called by muse, mutect2, varscan2
- PTGDR | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.531); catalogued as rs920131809, COSV100035743, COSV60094462; called by muse, mutect2, varscan2
- PTGFR | c.480C>G p.C160W | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100882358; called by muse, mutect2, varscan2
- PTPRA | c.1938C>G p.Y646* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV99400685; called by muse, mutect2, varscan2
- QRICH2 | c.1403G>A p.G468D | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99429741; called by muse, mutect2, varscan2
- RAB17 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80101911, COSV99221463; called by muse, mutect2, varscan2
- RAB3IP | c.313G>T p.D105Y (on ENST00000550536 / NM_175623.4; = p.D89Y on NM_022456.5) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV99923051, COSV99923680; called by muse, mutect2, varscan2
- RAI2 | c.1198A>G p.S400G | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100518550; called by muse, mutect2, varscan2
- RALA | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99143495; called by muse, mutect2, varscan2
- RALGAPA1 | c.5561T>G p.F1854C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99356157; called by muse, mutect2, varscan2
- RALGAPB | c.1675G>T p.V559F | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99485866; called by muse, mutect2, varscan2
- RANBP9 | c.1466G>T p.S489I | Missense Mutation (SNP) | VAF 46/70 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV99163632; called by muse, mutect2, varscan2
- RBM47 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV55934904, COSV99921706; called by muse, mutect2, varscan2
- RELCH | c.3526C>G p.Q1176E | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV99902825; called by muse, mutect2, varscan2
- RELN | c.9277C>A p.L3093I | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.273); catalogued as COSV100634963; called by muse, mutect2, varscan2
- RELN | c.5133C>A p.Y1711* | Nonsense Mutation (SNP) | VAF 58/104 reads (56%) | catalogued as COSV100634966; called by muse, mutect2, varscan2
- REPS2 | c.736A>G p.T246A | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100381674; called by muse, mutect2, varscan2
- RFPL4B | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.022); catalogued as COSV101480729; called by muse, varscan2
- RGPD2 | c.4102G>C p.E1368Q | Missense Mutation (SNP) | VAF 73/323 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100553132, COSV100553145; called by muse, mutect2, varscan2
- RIN3 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs774034330, COSV53645564; called by muse, mutect2, varscan2
- RIPOR1 | c.2674C>G p.L892V (on ENST00000379312 / NM_001193522.2; = p.L888V on NM_024519.4) | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV99243713; called by muse, mutect2, varscan2
- ROS1 | c.4138C>G p.L1380V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100877725; called by muse, mutect2, varscan2
- RP1L1 | c.1693C>A p.Q565K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV101223657; called by muse, mutect2, varscan2
- RPS6KA5 | c.2360A>T p.D787V | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs200886537, COSV100003264; called by muse, mutect2, varscan2
- RPS6KA5 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.883); catalogued as COSV100003267, COSV56224771; called by muse, mutect2, varscan2
- SAMD9L | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 93/152 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100561156; called by muse, mutect2, varscan2
- SCNN1G | c.1038G>T p.E346D | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.998); catalogued as COSV100264551; called by muse, mutect2, varscan2
- SCRN2 | c.1022C>G p.P341R | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99274347; called by muse, mutect2, varscan2
- SDSL | c.580G>C p.V194L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV100615310; called by muse, mutect2, varscan2
- SELP | c.2234A>T p.Q745L | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99741201; called by muse, mutect2, varscan2
- SEMA6D | c.949A>T p.T317S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.177); catalogued as COSV60383419; called by muse, mutect2, varscan2
- SENP5 | c.643A>G p.K215E | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV100052298; called by muse, mutect2
- SH3BP2 | c.1213C>A p.P405T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV100697052; called by muse, mutect2, varscan2
- SHOX | c.623C>A p.P208H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100479310; called by muse, mutect2, varscan2
- SHOX2 | c.545C>A p.A182D (on ENST00000441443 / NM_006884.3; = p.A206D on NM_003030.4) | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101273841; called by muse, mutect2
- SHROOM2 | c.678A>T p.K226N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.13); catalogued as COSV101099073; called by muse, mutect2, varscan2
- SI | c.374-1G>T p.X125_splice | Splice Site (SNP) | VAF 78/167 reads (47%) | catalogued as COSV100017282, COSV52265183; called by muse, mutect2, varscan2
- SIGLEC6 | c.188G>C p.G63A | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100585709; called by muse, mutect2, varscan2
- SLC22A8 | c.482C>A p.A161E | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100268109; called by muse, mutect2, varscan2
- SLC24A3 | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100043208, COSV60120983; called by muse, mutect2, varscan2
- SLC26A4 | c.1344G>T p.S448= | Splice Region (SNP) | VAF 17/58 reads (29%) | catalogued as COSV99707542; called by muse, mutect2, varscan2
- SLC30A1 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1410627495, COSV100879174; called by muse, mutect2, varscan2
- SLC37A1 | c.1192G>T p.G398C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.055); catalogued as COSV100721845; called by muse, mutect2, varscan2
- SLC5A12 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99745544, COSV99745627; called by muse, mutect2, varscan2
- SLC9A2 | c.1421T>C p.I474T | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs767819457, COSV99296885; called by muse, mutect2, varscan2
- SLC9C1 | c.2787G>A p.M929I | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV59888613, COSV99998867; called by muse, mutect2, varscan2
- SLIT2 | c.1462+2T>A p.X488_splice | Splice Site (SNP) | VAF 11/97 reads (11%) | catalogued as COSV99887533; called by muse, mutect2
- SLIT3 | c.1574G>T p.R525L | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs369305666, COSV100270104; called by muse, mutect2, varscan2
- SMARCAD1 | c.2338A>G p.K780E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100759040; called by muse, mutect2, varscan2
- SMC4 | c.3433A>G p.K1145E | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100557581; called by muse, mutect2, varscan2
- SMR3B | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV100513463; called by muse, mutect2, varscan2
- SNAPC4 | c.227A>T p.D76V | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100047714; called by muse, varscan2
- SNAPC4 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs1203775051, COSV100047717; called by muse, varscan2
- SOX5 | c.2249A>T p.Y750F | Missense Mutation (SNP) | VAF 98/250 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100508336; called by muse, mutect2, varscan2
- SPAG8 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as rs1197438823, COSV52414842; called by muse, mutect2, varscan2
- SPTAN1 | c.5654G>A p.W1885* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100824040; called by muse, mutect2, varscan2
- STOML2 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 23/107 reads (21%) | catalogued as COSV100521450; called by muse, mutect2, varscan2
- STYXL2 | c.1740C>A p.N580K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as COSV99609925; called by muse, mutect2, varscan2
- TAB2 | c.932A>G p.Q311R | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.373); catalogued as COSV99645138; called by muse, mutect2, varscan2
- TBRG4 | c.358T>A p.L120M | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.428); catalogued as COSV99345684; called by muse, mutect2, varscan2
- TET2 | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as rs757480389, COSV99484923; called by muse, mutect2, varscan2
- TICRR | c.793A>T p.K265* | Nonsense Mutation (SNP) | VAF 27/142 reads (19%) | catalogued as COSV99180195; called by muse, mutect2, varscan2
- TLR6 | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs199766026; called by muse, mutect2, varscan2
- TMEM132D | c.2688A>T p.R896S | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV101243105; called by muse, mutect2, varscan2
- TMEM132D | c.2106G>T p.R702S | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV67159939; called by muse, mutect2, varscan2
- TRIM51 | c.1040T>A p.M347K | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV99793185; called by mutect2, varscan2
- TRIM51 | c.1041G>T p.M347I | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV99793186; called by mutect2, varscan2
- TRIM58 | c.673C>A p.Q225K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as COSV63573006; called by muse, mutect2, varscan2
- TRPC3 | c.1529C>A p.T510N (on ENST00000379645 / NM_001366479.2; = p.T437N on NM_003305.2) | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV99313534; called by muse, mutect2, varscan2
- TTC38 | c.1381A>C p.K461Q | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV101123946; called by muse, mutect2, varscan2
- UGT2B17 | c.76G>T p.V26L | Missense Mutation (SNP) | VAF 62/415 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs1403147969, COSV100497313; called by muse, mutect2, varscan2
- UNC13C | c.1051G>C p.A351P | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.767); catalogued as COSV99523235; called by muse, mutect2, varscan2
- USP34 | c.7368+2T>C p.X2456_splice | Splice Site (SNP) | VAF 9/84 reads (11%) | catalogued as COSV101277237; called by muse, mutect2, varscan2
- USP47 | c.2570A>T p.E857V (on ENST00000399455 / NM_001372095.1; = p.E769V on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV100359984; called by muse, mutect2, varscan2
- USP9X | c.3157A>G p.T1053A | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100200136; called by muse, mutect2, varscan2
- VARS1 | c.3482G>C p.G1161A | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as COSV100791861; called by muse, mutect2
- VCAN | c.7567C>G p.R2523G | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV54111940, COSV99427410; called by muse, mutect2, varscan2
- VCX | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 21/291 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as rs1481858547, COSV100406406; called by muse, mutect2
- VPS35 | c.1469T>A p.L490H | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100140826; called by muse, mutect2, varscan2
- VSIG10 | c.1159A>G p.I387V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770379918, COSV100821369; called by muse, mutect2, varscan2
- VWA5A | c.1918G>C p.A640P | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100827970; called by muse, mutect2, varscan2
- WDR35 | c.2856G>C p.K952N (on ENST00000345530 / NM_001006657.2; = p.K941N on NM_020779.4) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV99853547; called by muse, mutect2, varscan2
- WDR49 | c.1815A>G p.I605M (on ENST00000308378 / NM_001366158.1; = p.I946M on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.127); catalogued as rs1242768570, COSV100393932, COSV57702326; called by muse, mutect2, varscan2
- WDR53 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100218154; called by muse, mutect2, varscan2
- WDR7 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99590507; called by muse, mutect2, varscan2
- WFIKKN2 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV100260125, COSV60959159; called by muse, mutect2
- ZAP70 | c.1820C>A p.P607H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as COSV99385978; called by muse, mutect2
- ZC3H12C | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.494); catalogued as COSV99585357; called by muse, mutect2, varscan2
- ZFHX4 | c.4538T>G p.M1513R | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.113); catalogued as rs763047268, COSV99268052; called by muse, mutect2, varscan2
- ZFHX4 | c.5063C>T p.P1688L | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99268055; called by muse, mutect2, varscan2
- ZFP14 | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 49/257 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV99525345; called by muse, mutect2, varscan2
- ZNF410 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs769091601, COSV57911507; called by muse, mutect2, varscan2
- ZNF415 | c.260G>T p.R87M | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV99702068; called by muse, mutect2, varscan2
- ZNF576 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.286); catalogued as COSV100338260; called by muse, mutect2, varscan2
- ZNF621 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100182805, COSV59457253; called by muse, mutect2, varscan2
- ZNF644 | c.1543G>T p.A515S | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100494746; called by muse, mutect2, varscan2
- ZNF804A | c.2687A>T p.E896V | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.231); catalogued as COSV100170314; called by muse, mutect2, varscan2
- C2CD2L | c.345C>A p.C115* | Nonsense Mutation (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2
- DCAF1 | c.1729G>C p.E577Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FFAR4 | c.29del p.G10Afs*108 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, varscan2
- LONP1 | c.2537_2538+16del p.X846_splice | Splice Site (DEL) | VAF 13/146 reads (9%) | called by mutect2, pindel
- NFKBIZ | c.1237_1240del p.L413Gfs*54 | Frame Shift Del (DEL) | VAF 20/182 reads (11%) | called by mutect2, pindel
- NUBP2 | c.344del p.K115Sfs*31 | Frame Shift Del (DEL) | VAF 68/280 reads (24%) | called by mutect2, pindel, varscan2
- RASSF1 | c.390_391dup p.T131Rfs*27 (on ENST00000357043 / NM_170714.2; = p.T127Rfs*27 on NM_007182.5) | Frame Shift Ins (INS) | VAF 25/51 reads (49%) | called by mutect2, pindel, varscan2
- RFPL4B | c.663del p.F221Lfs*39 | Frame Shift Del (DEL) | VAF 16/110 reads (15%) | called by pindel, varscan2
- RNASE11 | c.119del p.A40Efs*13 | Frame Shift Del (DEL) | VAF 75/200 reads (38%) | called by mutect2, pindel, varscan2
- SBNO1 | c.3416A>C p.N1139T (on ENST00000420886; = p.N1138T on NM_018183.5) | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TRGC1 | c.167G>C p.G56A | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- A2M | c.2949C>T p.N983= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs1399086522, COSV100589041; called by muse, mutect2, varscan2
- ADAD1 | c.234T>A p.P78= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as COSV99636310; called by muse, mutect2, varscan2
- ADAMTS9 | c.4002T>A p.T1334= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV99900268; called by muse, mutect2, varscan2
- AGA | c.906G>C p.G302= | Silent (SNP) | VAF 28/151 reads (19%) | catalogued as COSV99219717; called by muse, mutect2, varscan2
- AMFR | c.1260C>T p.H420= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as rs369924336; called by muse, mutect2, varscan2
- ANKRD11 | c.1080G>A p.P360= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as rs144902113; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARL4C | c.540G>T p.L180= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100327109; called by muse, mutect2, varscan2
- ATP2B3 | c.1867C>A p.R623= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV54848973, COSV99685919; called by muse, mutect2, varscan2
- BRD8 | c.702G>T p.L234= (on ENST00000254900 / NM_139199.2; = p.L307= on NM_006696.4) | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV99137697; called by muse, mutect2, varscan2
- CCDC22 | c.978G>C p.T326= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100873125, COSV100873270, COSV66051828; called by muse, mutect2
- CCNYL1 | c.396A>T p.T132= (on ENST00000295414 / NM_001330218.2; = p.T62= on NM_152523.2) | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV99776091; called by muse, mutect2, varscan2
- CDH19 | c.1485T>C p.D495= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as COSV100052402; called by muse, mutect2, varscan2
- CHD5 | c.1902C>T p.Y634= | Silent (SNP) | VAF 40/192 reads (21%) | catalogued as rs772371613, COSV99315116; called by muse, mutect2, varscan2
- CNTN1 | c.666G>T p.V222= | Silent (SNP) | VAF 37/160 reads (23%) | catalogued as COSV100751925; called by muse, mutect2, varscan2
- CNTNAP5 | c.1152C>G p.P384= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs967697335, COSV70488635, COSV70505169, COSV70510848; called by muse, mutect2, varscan2
- COLGALT2 | c.1072C>A p.R358= | Silent (SNP) | VAF 59/380 reads (16%) | catalogued as COSV100730882, COSV62300394; called by muse, mutect2, varscan2
- CSMD3 | c.3777C>A p.L1259= (on ENST00000297405 / NM_001363185.1; = p.L1155= on NM_052900.3) | Silent (SNP) | VAF 22/151 reads (15%) | catalogued as COSV99846828, COSV99848632; called by muse, mutect2, varscan2
- CTNNBL1 | c.561T>A p.A187= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV100799906; called by muse, mutect2, varscan2
- DLGAP3 | c.189G>A p.L63= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99333218; called by muse, mutect2
- DNAH3 | c.1356G>T p.L452= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV99770762; called by muse, mutect2, varscan2
- DNAH8 | c.7389T>C p.T2463= | Silent (SNP) | VAF 34/135 reads (25%) | catalogued as COSV100547277; called by muse, mutect2, varscan2
- DYNC1LI2 | c.396C>T p.L132= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs1461736318, COSV99263006; called by muse, mutect2, varscan2
- FANCA | c.4176C>A p.P1392= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV99235357; called by muse, mutect2, varscan2
- FBXO41 | c.1224A>G p.P408= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99721578; called by muse, mutect2, varscan2
- FNDC4 | c.657G>T p.V219= | Silent (SNP) | VAF 40/202 reads (20%) | catalogued as COSV99254076; called by muse, mutect2, varscan2
- FPR2 | c.723G>C p.R241= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100389473; called by muse, mutect2, varscan2
- FREM2 | c.6111G>C p.L2037= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV99751092; called by muse, mutect2, varscan2
- GZF1 | c.798G>T p.P266= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as COSV100582564, COSV57636612; called by muse, mutect2, varscan2
- HCN1 | c.2526C>T p.F842= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV57532582; called by muse, mutect2, varscan2
- HERC2 | c.12903G>A p.K4301= | Silent (SNP) | VAF 72/209 reads (34%) | catalogued as COSV99876883; called by muse, mutect2, varscan2
- HES1 | c.282G>T p.A94= | Silent (SNP) | VAF 22/210 reads (10%) | catalogued as COSV99220613; called by muse, mutect2, varscan2
- HTR5A | c.495C>T p.T165= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99840008; called by muse, mutect2, varscan2
- HTR7 | c.588G>A p.G196= | Silent (SNP) | VAF 26/176 reads (15%) | catalogued as COSV53294293; called by muse, mutect2, varscan2
- HYDIN | c.6600C>G p.G2200= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99993746; called by muse, mutect2, varscan2
- INSC | c.69C>T p.V23= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs766635308, COSV101089714; called by muse, mutect2, varscan2
- KCNK18 | c.444C>A p.L148= | Silent (SNP) | VAF 59/323 reads (18%) | catalogued as COSV100572150; called by muse, mutect2, varscan2
- KCNQ2 | c.1083G>A p.Q361= | Silent (SNP) | VAF 27/128 reads (21%) | catalogued as COSV100610575; called by muse, mutect2, varscan2
- KCNV1 | c.1422G>T p.R474= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV99819432; called by muse, mutect2, varscan2
- KIF16B | c.3489A>G p.L1163= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100734963; called by muse, mutect2, varscan2
- LCT | c.681G>T p.P227= | Silent (SNP) | VAF 37/237 reads (16%) | catalogued as COSV99930519; called by muse, mutect2, varscan2
- LRIT2 | c.366G>C p.A122= | Silent (SNP) | VAF 27/206 reads (13%) | catalogued as COSV100928354; called by muse, mutect2, varscan2
- MAOA | c.1413C>T p.I471= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs1372840857, COSV100109054; called by muse, mutect2, varscan2
- MAP3K14 | c.2412C>T p.S804= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs916482018, COSV100766568; called by muse, mutect2
- MAP9 | c.699T>G p.L233= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV100251123; called by muse, mutect2, varscan2
- MMP12 | c.1371T>A p.R457= | Silent (SNP) | VAF 54/105 reads (51%) | catalogued as COSV100405089; called by muse, mutect2, varscan2
- MMP17 | c.714C>T p.H238= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as rs764549950, COSV100861982; called by muse, mutect2, varscan2
- MMP21 | c.18C>T p.I6= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV100916697; called by muse, mutect2, varscan2
- NACA2 | c.211C>A p.R71= | Silent (SNP) | VAF 36/327 reads (11%) | catalogued as COSV101478576, COSV71713103; called by muse, mutect2, varscan2
- NEU4 | c.1248C>A p.P416= (on ENST00000391969 / NM_001167602.3; = p.P428= on NM_080741.4) | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV100372210; called by muse, mutect2, varscan2
- NFIC | c.519C>G p.V173= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV100545673; called by muse, mutect2, varscan2
- OLFML2B | c.2163G>C p.T721= | Silent (SNP) | VAF 45/287 reads (16%) | catalogued as COSV99668957; called by muse, mutect2, varscan2
- OR10G4 | c.168C>A p.P56= | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as COSV100305007; called by muse, mutect2, varscan2
- OR1B1 | c.171G>T p.L57= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs764045063, COSV59171313; called by muse, mutect2, varscan2
- OR2C3 | c.888G>T p.T296= | Silent (SNP) | VAF 47/88 reads (53%) | catalogued as COSV100825798, COSV63575105; called by muse, mutect2, varscan2
- OR2T3 | c.60G>A p.T20= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs1222109609, COSV100613456, COSV62082915; called by muse, mutect2, varscan2
- OR2T34 | c.60G>A p.T20= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as rs562220823, COSV100170565; called by muse, mutect2, varscan2
- OR52N5 | c.144G>T p.V48= | Silent (SNP) | VAF 31/141 reads (22%) | catalogued as COSV100399782; called by muse, mutect2, varscan2
- OR6Y1 | c.18G>A p.L6= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as COSV100225506; called by muse, mutect2, varscan2
- PADI6 | c.1194T>C p.I398= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100640027; called by muse, mutect2, varscan2
- PDSS2 | c.138G>C p.P46= | Silent (SNP) | VAF 18/143 reads (13%) | catalogued as COSV100941909; called by muse, mutect2, varscan2
- PEX5L | c.1494C>T p.N498= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as rs1227024144, COSV55854194; called by muse, mutect2
- PKP2 | c.1845C>A p.S615= | Silent (SNP) | VAF 20/228 reads (9%) | catalogued as COSV99298519; called by muse, mutect2
- PPP1R9A | c.2718T>C p.S906= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV99198886; called by muse, mutect2, varscan2
- PRDM16 | c.3633G>A p.V1211= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV99579062; called by muse, mutect2, varscan2
- PROSER1 | c.2271C>T p.V757= | Silent (SNP) | VAF 33/170 reads (19%) | catalogued as COSV100613069; called by muse, mutect2, varscan2
- PTCD1 | c.1836C>T p.D612= | Silent (SNP) | VAF 58/214 reads (27%) | catalogued as COSV99464588; called by muse, mutect2, varscan2
- PXDN | c.1785G>T p.V595= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV99414994; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1488G>C p.T496= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as COSV100365800; called by muse, mutect2, varscan2
- RELN | c.8193C>G p.L2731= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as COSV58986761; called by muse, mutect2, varscan2
- SETD6 | c.628C>T p.L210= (on ENST00000219315 / NM_001160305.4; = p.L186= on NM_024860.3) | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs771901214, COSV99262584; called by muse, mutect2, varscan2
- SLC19A3 | c.204G>T p.L68= | Silent (SNP) | VAF 62/212 reads (29%) | catalogued as COSV99296132; called by muse, mutect2, varscan2
- SLC25A12 | c.1728T>C p.F576= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs1452641178, COSV99785448; called by muse, mutect2, varscan2
- SMG1 | c.4245C>G p.V1415= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV101246884; called by muse, mutect2, varscan2
- SOGA1 | c.2160G>T p.L720= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV99415430; called by muse, mutect2, varscan2
- SPAG17 | c.3993C>T p.H1331= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100310672; called by muse, mutect2, varscan2
- SPIN2A | c.513C>A p.V171= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100888070; called by mutect2, varscan2
- STARD13 | c.1035G>A p.T345= (on ENST00000336934 / NM_001243476.3; = p.T227= on NM_052851.3) | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs768240114, COSV99716404; called by muse, mutect2, varscan2
- SWT1 | c.810G>T p.L270= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as COSV100833552; called by muse, mutect2, varscan2
- TBC1D17 | c.1299C>T p.N433= | Silent (SNP) | VAF 25/172 reads (15%) | catalogued as rs201269112, COSV55580573; called by muse, varscan2
- TENM4 | c.4179C>T p.L1393= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV99579581; called by muse, mutect2, varscan2
- TENM4 | c.3102C>T p.S1034= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV99579588; called by muse, mutect2, varscan2
- TMEM132D | c.2952A>G p.Q984= | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as COSV101243104; called by muse, mutect2, varscan2
- TRIB2 | c.871C>A p.R291= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV50225317, COSV50227136, COSV99331358; called by muse, mutect2, varscan2
- TRIM42 | c.369C>T p.S123= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as rs1559935333, COSV99648862; called by muse, mutect2, varscan2
- TSPYL2 | c.486G>T p.P162= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100212063, COSV100212427; called by muse, mutect2, varscan2
- WDPCP | c.1473C>T p.I491= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV55428912, COSV99706983; called by muse, mutect2, varscan2
- XIRP2 | c.84C>G p.P28= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV54689446, COSV99747770; called by muse, mutect2, varscan2
- ZBTB20 | c.1641G>C p.L547= (on ENST00000474710 / NM_001164342.2; = p.L474= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 41/186 reads (22%) | catalogued as COSV100615341; called by muse, mutect2, varscan2
- ZDBF2 | c.3285C>T p.D1095= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100985570; called by muse, mutect2, varscan2
- ZFHX4 | c.2757C>T p.A919= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV50628690; called by muse, mutect2, varscan2
- ZFYVE16 | c.1347A>G p.E449= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100566659; called by muse, mutect2, varscan2
- ZMYM3 | c.3534A>T p.T1178= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100078406; called by muse, mutect2, varscan2
- ZNF324 | c.924C>T p.S308= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs750522890, COSV99543318; called by muse, mutect2, varscan2
- ADGRE4P | n.178T>G | RNA (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- HERC2P3 | n.57G>A | RNA (SNP) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- HTR2C | c.-79-11618G>A | Intron (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99351115; called by muse, mutect2, varscan2
- MKNK1 | c.-2-2549A>T | Intron (SNP) | VAF 53/124 reads (43%) | catalogued as COSV100361524; called by muse, mutect2, varscan2
- SLIT2 | c.1463-577G>T | Intron (SNP) | VAF 9/42 reads (21%) | catalogued as COSV56566339, COSV99887535; called by mutect2, varscan2
- SNORA71E | n.76G>T | RNA (SNP) | VAF 28/183 reads (15%) | called by muse, mutect2, varscan2
- SNORD115-43 | n.28C>G | RNA (SNP) | VAF 133/371 reads (36%) | called by muse, mutect2, varscan2
- SV2C | c.581-21040C>G | Intron (SNP) | VAF 38/323 reads (12%) | called by muse, mutect2, varscan2
- SV2C | c.581-21039G>A | Intron (SNP) | VAF 37/323 reads (11%) | catalogued as rs762596965; called by muse, mutect2, varscan2
- UBTFL2 | n.138G>C | RNA (SNP) | VAF 24/167 reads (14%) | called by muse, mutect2, varscan2
